Somatic mutation profile of tumor specimen 0DWBCD from CCDI case PBCNVY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 9.8 years (3,576 days).
Specimen 0DWBCD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 502df828-94d4-48e3-b1ff-2d672a8870e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWBCP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fb9b370-61cf-4030-9a93-6be3efb55e03

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH1 | c.390C>G p.C130W | Missense Mutation (SNP) | VAF 434/1494 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV70549532, COSV70550938; called by muse, varscan2
- FAM234A | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 142/340 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs559036158; called by muse, varscan2
- SASH1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 360/724 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs1050414808, COSV66559930; called by muse, varscan2
- FLG | c.6862G>C p.D2288H | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, varscan2
- NCOA6 | c.6000-2A>C p.X2000_splice | Splice Site (SNP) | VAF 56/551 reads (10%) | called by muse, varscan2
- ZNF548 | c.1242C>T p.V414= | Silent (SNP) | VAF 208/486 reads (43%) | called by muse, varscan2
